Somatic mutation profile of tumor specimen TCGA-EK-A2RM-01A (aliquot TCGA-EK-A2RM-01A-21D-A18J-09) from TCGA case TCGA-EK-A2RM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 40.6 years (14,842 days).
Specimen TCGA-EK-A2RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61c57d3c-7ba5-4a48-9958-111913a9e0ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RM-10A (Blood Derived Normal), aliquot TCGA-EK-A2RM-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52e1e5b7-73ba-4e61-bfcc-14529bd8de33

The open-access MAF lists 90 somatic variants for this specimen: 66 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 22, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 1, Splice Region 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPRV1 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV57228309; called by muse, mutect2, varscan2
- BSCL2 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs879253900, COSV54016272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1orf112 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99610284; called by muse, mutect2
- CDH22 | c.596C>A p.T199K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100953006; called by muse, mutect2, varscan2
- CEP104 | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV65518169; called by muse, mutect2, varscan2
- CLTCL1 | c.4631C>T p.S1544L (on ENST00000427926 / NM_007098.4; = p.S1487L on NM_001835.4) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782403211, COSV104371906; called by muse, mutect2, varscan2
- CSMD3 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.631); catalogued as COSV99851206; called by muse, mutect2
- ERBB2 | c.2921C>T p.S974F | Missense Mutation (SNP) | VAF 125/1406 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV54082978; called by muse, mutect2
- ERBB2 | c.3098del p.P1033Qfs*27 | Frame Shift Del (DEL) | VAF 71/734 reads (10%) | catalogued as COSV54064881; called by mutect2, pindel
- FAM104A | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs569512877, COSV52145050, COSV99277817; called by muse, mutect2, varscan2
- FAM83F | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV61000186; called by muse, mutect2, varscan2
- FTO | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as COSV67109808; called by muse, mutect2
- GAB3 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs781898962; called by muse, mutect2, varscan2
- GTDC1 | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.088); catalogued as COSV99599090, COSV99601194; called by muse, mutect2, varscan2
- KHDC4 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1347228839, COSV64164853; called by muse, mutect2, varscan2
- KIF15 | c.3172-1G>A p.X1058_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100393377; called by muse, mutect2, varscan2
- LTBP1 | c.2242C>T p.H748Y (on ENST00000404816 / NM_206943.4; = p.H422Y on NM_000627.4) | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as COSV100618067; called by muse, mutect2
- MAML1 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767452281; called by muse, mutect2, varscan2
- NMD3 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs369937656; called by muse, mutect2, varscan2
- OSBPL7 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as rs1199621364; called by muse, mutect2, varscan2
- PHF3 | c.3322C>T p.Q1108* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100013465; called by muse, mutect2, varscan2
- PRKDC | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1307192376, COSV50625002; called by muse, mutect2, varscan2
- SLC13A1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV52014007; called by muse, mutect2, varscan2
- SLC35F3 | c.82G>A p.E28K (on ENST00000366617 / NM_001300845.1; = p.E97K on NM_173508.4) | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.25); PolyPhen benign (0.162); catalogued as rs1167555801; called by muse, mutect2, varscan2
- SLC39A10 | c.1976C>A p.S659Y | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV62766919; called by muse, mutect2, varscan2
- SLC44A5 | c.1130C>A p.T377N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1021472543; called by muse, mutect2, varscan2
- SMARCA2 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.203); catalogued as COSV61804606; called by muse, mutect2, varscan2
- TMEM132D | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375620383; called by muse, mutect2, varscan2
- TMEM87B | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs755041108; called by muse, mutect2, varscan2
- TNN | c.3829C>T p.H1277Y | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99513312; called by muse, mutect2
- VPS39 | c.1483G>A p.V495M (on ENST00000348544 / NM_001301138.2; = p.V484M on NM_015289.5) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs745531772, COSV58793364; called by muse, mutect2, varscan2
- ZNF548 | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV60241425; called by muse, mutect2, varscan2
- ADGRA2 | c.1630G>C p.E544Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ARHGEF37 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 20/30 reads (67%) | called by muse, mutect2, varscan2
- ARL14EP | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CDC42BPB | c.3514A>G p.I1172V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CEP63 | c.89A>T p.K30I | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPAMD8 | c.2988G>A p.E996= (on ENST00000651564; = p.E949= on NM_015692.5) | Splice Region (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- CPSF1 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CPSF1 | c.2201C>A p.S734* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- DCAF8L1 | c.1625C>A p.S542* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- GCA | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | called by muse, mutect2, varscan2
- HYDIN | c.7217_7221del p.V2406Gfs*6 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- IP6K2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNK9 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KEAP1 | c.1774_1780del p.S592* | Frame Shift Del (DEL) | VAF 30/53 reads (57%) | called by mutect2, pindel, varscan2
- MED13L | c.2249G>T p.G750V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MORC4 | c.1052T>G p.V351G | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- NCEH1 | c.1147C>G p.L383V (on ENST00000538775; = p.L343V on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- NPFFR2 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR8H1 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- POU6F1 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PRKDC | c.1943C>G p.S648* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- PRTG | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PWWP3B | c.177T>G p.N59K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RAG1 | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RASGRP3 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- RC3H1 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SCN7A | c.1709A>C p.N570T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- SLCO1B1 | c.1678G>T p.V560F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- SNX21 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- TXNDC2 | c.1072G>T p.D358Y (on ENST00000306084 / NM_001098529.2; = p.D291Y on NM_032243.6) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- WDR25 | c.444C>A p.F148L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK4 | c.3360G>C p.L1120F | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ZBTB32 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ZNF280A | c.392A>G p.Q131R | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.405); called by muse, mutect2
- ARID3B | c.1404C>T p.I468= | Silent (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- BFSP1 | c.1884C>T p.I628= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs181266441; called by muse, mutect2, varscan2
- CASS4 | c.939C>T p.G313= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- CYP3A7 | c.1488G>A p.R496= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs199645882; called by muse, mutect2, varscan2
- EML3 | c.2340G>C p.L780= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- FAM189A2 | c.1221G>A p.L407= | Silent (SNP) | VAF 51/71 reads (72%) | called by muse, mutect2, varscan2
- FCGR1A | c.657G>A p.Q219= | Silent (SNP) | VAF 45/183 reads (25%) | called by muse, mutect2, varscan2
- KCTD17 | c.609C>T p.S203= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as rs748740845; called by muse, mutect2, varscan2
- LRRC57 | c.321C>G p.L107= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs749221618; called by muse, mutect2, varscan2
- MTNR1B | c.9G>A p.E3= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs967432159; called by muse, mutect2, varscan2
- NBEAL2 | c.6573C>G p.S2191= | Silent (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2
- NEFL | c.24G>A p.P8= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs1227374739, COSV99647810; called by muse, mutect2, varscan2
- RASEF | c.948G>A p.L316= | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as rs138365424; called by muse, mutect2, varscan2
- RPL18 | c.342C>T p.L114= | Silent (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- RPP25 | c.405C>A p.L135= | Silent (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- SLC5A12 | c.1575A>C p.I525= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV101237783; called by muse, mutect2, varscan2
- SPTBN4 | c.1053C>T p.F351= | Silent (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2, varscan2
- TRHDE | c.1416T>C p.V472= | Silent (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- TSSK6 | c.636C>T p.F212= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV53064025; called by muse, mutect2, varscan2
- TTC27 | c.69G>A p.Q23= | Silent (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- VCAN | c.9360C>T p.S3120= | Silent (SNP) | VAF 38/59 reads (64%) | catalogued as rs760243636; called by muse, mutect2, varscan2
- ZNF234 | c.243G>A p.K81= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824557 T>C | 5'Flank (SNP) | VAF 54/166 reads (33%) | catalogued as rs761810364; called by muse, mutect2, varscan2
- SSX6P | n.200C>T | RNA (SNP) | VAF 15/385 reads (4%) | called by muse, mutect2
